Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-5499, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-5499-01A (Primary Tumor).

PATIENT HISTORY:

The patient is a [REDACTED] with a history of PSA value of 5.2. The patient also has a history of biopsy on [REDACTED]. This biopsy reveals: poorly-differentiated prostatic adenocarcinoma in the right base, right mid, right apex, left base and left mid of the prostate and high grade prostatic intraepithelial neoplasia in the left apex of the prostate. The patient suffered a pneumothorax in [REDACTED].

PRE-OP DIAGNOSIS: Prostate cancer.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Radical prostatectomy.

TCGA - EJ - 5499

FINAL DIAGNOSIS:

PART 1: LYMPH NODES, RIGHT PELVIC, EXCISION -
NO EVIDENCE OF NEOPLASIA IN 11 LYMPH NODES (0/11).

PART 2: LYMPH NODES, LEFT PELVIC, EXCISION -
NO EVIDENCE OF NEOPLASIA IN 8 LYMPH NODES (0/8).

PART 3: PROSTATE, BILATERAL SEMINAL VESICLES AND VAS DEFERENTIA, RADICAL PROSTATECTOMY -

- A. PROSTATE ADENOCARCINOMA, GLEASON SCORE 4 + 3 = 7.
- B. MICROSCOPIC FOCI OF GLEASON PATTERN 5 ARE SEEN AND ACCOUNT FOR LESS THAN 1% OF THE TUMOR.
- C. THE CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT LOBES AND HAS A GREATEST NODULAR DIAMETER OF 2.3 CM IN ONE HISTOLOGIC SECTION (SLIDE HH).
- D. THE CARCINOMA INVOLVES APPROXIMATELY 20% OF THE EXAMINED PROSTATE VOLUME.
- E. THE CARCINOMA SHOWS MULTIFOCAL ESTABLISHED EXTRACAPSULAR EXTENSION.
- F. THE EXTRACAPSULAR EXTENSION IS SEEN IN THE REGION AROUND THE RIGHT SEMINAL VESICLE (3A), THE RIGHT ANTERIOR BASE (3P, 3Q), POSTERIOR RIGHT APEX (3X), RIGHT MID (3Y), RIGHT BASE (3Z), POSTERIOR LEFT APEX (3AA), AND POSTERIOR LEFT MID (3BB).
- G. BILATERAL SEMINAL VESICLES, FREE OF CARCINOMA.
- H. ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF CARCINOMA.
- I. PERINEURAL INVASION IS IDENTIFIED.
- J. HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- K. PATHOLOGIC TNM STAGE: pT3a N0 MX.

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY PROSTATE TUMORS**

CLINICAL DATA:	PSA value: 5.2
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	4
SECONDARY GLEASON GRADE:	3
GLEASON SUM SCORE:	7
GLEASON 4/5 PERCENTAGE:	80%
WEIGHT OF PROSTATE:	46.75gm
TUMOR SIZE:	Maximum dimension: 2.3 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	5 - 25%
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - multifocal
EXTRAPROSTATIC EXTENSION:	Yes - Established (> 0.8mm)
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	No
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
LYMPH NODES EXAMINED:	20
LYMPH NODES POSITIVE:	0
EXTRANODAL EXTENSION:	No
T STAGE, PATHOLOGIC:	pT3a
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

Source: NCI Genomic Data Commons file 32ebcc65-f661-4122-8b1b-d20dadfd7aae (TCGA-EJ-5499.F69E29DA-24D1-45F2-9B4F-A32F9E5479A4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).